Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6403, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6403-01A (Primary Tumor).

TCGA-DU-6403

AGE/SEX: [REDACTED]

DOB: [REDACTED]

SURGERY DATE: [REDACTED]

RECEIVE DATE: [REDACTED]

PATHOLOGICAL DIAGNOSIS:

RIGHT TEMPORAL LOBE, BIOPSY: ANAPLASTIC GLIOMA, MIXED (ASTROCYTOMA AND OLIGODENDROGLIOMA), MIB-1, 15%.

Operation/Specimen:

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

A,B. Multiple 0.2-0.4 cm tissue. Frozen section diagnosis: Glioma.
In #1 and #3.

C.

SPECIMEN: Tumor.

FIXATIVE: Saline.

GENERAL: Multiple fragments of friable brain tissue, loosely aggregating to 4.5 x 4 x 1 cm. Serially sectioned.

SECTIONS: X1-X3 - representative.

[REDACTED] pc4 [REDACTED]

MICROSCOPIC: Sections show a hypercellular glioma with features of astrocytoma and oligodendroglioma. mitotic figures and vascular proliferation are present, more frequent in astrocytoma component. Scattered calcification is noted. Tumor necrosis is not seen in the sections. The MIB-1 labelling index is about 15%.

[REDACTED]

Source: NCI Genomic Data Commons file 1df538d5-33ac-4bcc-9f66-9598662e6272 (TCGA-DU-6403.86C8B229-D75E-48CE-849E-BCC995B186A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).